Gene-level copy-number profile of tumor specimen TCGA-VQ-A8PX-01A from TCGA case TCGA-VQ-A8PX, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 51.8 years (18,902 days).
Specimen TCGA-VQ-A8PX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.52db4a9f-f24a-42bb-914d-b03f9eee3cfe.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8PX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1f0bc05f-09ff-49b3-ba0f-716cf3119c59

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 303; copy number 2: 11,009; copy number 3: 30,841; copy number 4: 8,626; copy number 5: 5,985; copy number 6: 533; copy number 7: 2,497; copy number 10: 23; copy number 12: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8PX-01A-12D-A40Z-01): tumor purity 0.41, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:58,862,600–58,986,480, 2 genes (within-gene range 0–3): ZNF532, RNU2-69P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,521 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:220,450,679–222,656,092, 23 genes, copy number 10 (within-gene range 6–10): AC067956.1, AC093843.1, AC093843.2, AC011233.1, AC011233.2, EPHA4, TMEM256P2, AC079834.1, RPL23P5, AC068489.1, LLPHP3, HSPA9P1, RPL23AP28, PAX3, CCDC140, AC010980.1, CT75, Y_RNA, SGPP2, NANOGP2, RNU6-619P, GAPDHP49, FARSB.
- chr4:66,897,262–67,701,155, 10 genes, copy number 7: RNU6-699P, AC104806.2, RNU1-63P, RNA5SP527, AC104806.1, CENPC, STAP1, AC096720.2, UBA6, AC096720.1.
- chr4:67,716,375–67,773,854, 6 genes, copy number 7: ST3GAL1P1, AC079880.1, AC079880.2, GNRHR, SNORA62, TMPRSS11CP.
- chr4:91,319,034–91,325,306, 1 gene, copy number 12: AC074124.1.
- chr8:150,584–145,066,685, 2,481 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 303. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
